FM case AD12615 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/7a012a45-7cf7-472e-8804-1e6f9563a3ee

Male, 51.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 10% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
